Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6CY, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6CY-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery: .

Localisation: R frontal

Diagnosis: anaplastic oligoastrocytoma (grade III WHO)

Name of Pathologist:

ICD-O-3

Oligoastrocytoma, anaplastic
C66CF 9382/3
Site: Brain, supratentorial NOS
C71.0

path
R Brain, frontal lobe
C71.1
W 5/16/13

Source: NCI Genomic Data Commons file e853a11e-af57-4ecd-8b20-32f11be79b0e (TCGA-QH-A6CY.F47D9AFD-E511-450E-9F15-E1EDBF0FC87F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).